Gene-level copy-number profile of tumor specimen ALCH-B1YU-TTP1-A from ALCHEMIST case ALCH-B1YU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,336 days).
Specimen ALCH-B1YU-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa360284-4d2d-4152-9817-1c82d155039f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/0758bee5-8ed3-4ffc-bdcb-56d561f7f9a1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 129; copy number 1: 6,740; copy number 2: 50,288; copy number 3: 1,281; copy number 4: 60; copy number 5: 101; copy number 6: 237; copy number 7: 54; copy number 8: 2; copy number 9: 15; copy number 10: 1; copy number 15: 3; copy number 32: 1.

Homozygous deletions (total copy number 0; autosomes only): 96 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:4,654,609–4,792,534, 2 genes: AJAP1, Z98886.1.
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–2): AL139423.1.
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr1:228,203,503–228,213,664, 1 gene (within-gene range 0–2): OBSCN-AS1.
- chr2:20,200,797–20,225,433, 1 gene: SDC1.
- chr2:130,830,978–130,836,994, 1 gene (within-gene range 0–2): AC133785.1.
- chr2:231,523,187–231,713,551, 8 genes: NMUR1, RPL21P35, RPL23AP26, TEX44, RN7SL499P, PTMA, U4, MIR1244-1.
- chr3:46,668,995–46,710,886, 2 genes: ALS2CL, TMIE.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr6:57,919,784–57,930,291, 1 gene: GUSBP4.
- chr7:603,185–608,482, 1 gene (within-gene range 0–2): PRKAR1B-AS1.
- chr7:44,138,864–44,141,332, 1 gene: MYL7.
- chr7:66,505,155–66,592,397, 4 genes (within-gene range 0–2): AC008267.1, AC008267.3, AC006001.3, AC006001.4.
- chr7:97,984,684–97,998,622, 2 genes: OCM2, RN7SL478P.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–2): MIR601.
- chr9:137,205,685–137,236,555, 5 genes: NDOR1, RNF208, CYSRT1, RNF224, SLC34A3.
- chr10:6,245,731–6,245,831, 1 gene: Y_RNA.
- chr10:103,302,796–103,351,144, 2 genes: PCGF6, RNU11-3P.
- chr11:537,527–554,912, 1 gene (within-gene range 0–3): LRRC56.
- chr11:2,928,273–2,929,420, 1 gene: PHLDA2.
- chr12:111,360,651–111,403,310, 3 genes: PHETA1, LINC02356, HSPA8P14.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:102,501,676–102,539,726, 3 genes (within-gene range 0–2): RNU6-244P, ANKRD9, MIR4309.
- chr14:102,582,888–102,583,177, 1 gene: RN7SL546P.
- chr14:104,138,723–104,180,894, 1 gene: KIF26A.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr16:566,995–584,109, 3 genes (within-gene range 0–2): PIGQ, NHLRC4, Z98883.1.
- chr16:4,796,968–4,802,880, 1 gene: ROGDI.
- chr16:89,818,179–89,938,761, 7 genes: SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:2,337,498–2,381,058, 3 genes (within-gene range 0–2): SGSM2, AC006435.3, AC006435.2.
- chr17:21,376,357–21,419,870, 1 gene: KCNJ12.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,727,564, 2 genes (within-gene range 0–2): AC127024.7, AC127024.3.
- chr17:41,609,778–41,615,899, 1 gene: KRT16.
- chr18:79,470,120–79,470,940, 1 gene (within-gene range 0–1): AC018445.1.
- chr19:35,666,516–35,813,299, 19 genes: UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2.
- chr19:43,525,497–43,536,130, 1 gene (within-gene range 0–2): ZNF575.
- chr20:3,208,868–3,239,559, 2 genes: ITPA, SLC4A11.
- chr21:44,158,740–44,160,076, 1 gene: LINC01678.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 414 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:74,796,144–74,851,551, 1 gene, copy number 7: GTF2IRD2.
- chr14:104,857,792–104,858,836, 1 gene, copy number 8: AL583810.1.
- chr19:29,811,991–30,713,538, 11 genes, copy number 6–10 (within-gene range 2–10): CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536.
- chr19:32,243,965–32,244,083, 1 gene, copy number 5: RNA5SP472.
- chr19:39,196,964–41,018,398, 108 genes, copy number 6–9 (broad region; genes not listed).
- chr19:52,190,048–52,597,345, 26 genes, copy number 7 (within-gene range 1–7): PPP2R1A, MIR6801, AC010320.2, AC010320.5, Y_RNA, ZNF766, MIR643, AC010320.3, ZNF480, AC010320.4, ZNF610, ZNF880, ZNF528-AS1, AC010332.1, ZNF528, DPPA5P1, ZNF534, ZNF578, AC010332.3, AC010332.2, AC022150.3, ZNF808, ZNF701, RPL39P34, AC022150.1, ZNF137P.
- chr19:53,616,802–55,836,800, 231 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:56,189,570–56,538,575, 29 genes, copy number 5: ZSCAN5B, ZSCAN5C, AC011506.1, ZSCAN5A, ZSCAN5DP, EDDM13, AC006116.5, AC006116.7, Y_RNA, VN2R17P, AC006116.1, AC006116.3, AC006116.2, AC006116.6, AC006116.8, ZNF542P, ZNF582, AC006116.9, SLC25A36P1, AC006116.4, ZNF582-AS1, ZNF583, ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–32 (within-gene range 0–32): PWP2, GATD3A.
- chr21:44,200,602–44,244,993, 4 genes, copy number 8–15: AP001057.1, ICOSLG, AP001059.2, AP001059.1.

Autosomal genes at a single copy (total copy number 1): 3,931. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
